CGCI case BLGSP-71-19-00108 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e086f9bd-dd66-4f90-923b-1f53d95916fe

Demographics
Sex at birth: female; Race: white; Age at index: 15 years; Vital status: Dead; Days to death: 259 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Spleen; Classification of tumor: primary; Age at diagnosis: 15.9 years (5,803 days); Year of diagnosis: 1990; Method of diagnosis: Excisional Biopsy; Ann Arbor pathologic stage: Stage III; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 268 days; Ann Arbor extranodal involvement: Yes; Burkitt lymphoma clinical variant: Sporadic, pediatric; Max tumor bulk site: Other; Sites of involvement: Bone, NOS / Kidney, NOS / Ovary, NOS / Mediastinal soft tissue / Chest wall.
   Pathology details: Bone marrow malignant cells: No; Lymph node involved site: Axillary; Lymph nodes tested: 1.
   Pathology details: Lymph node involved site: Splenic.
   Pathology details: Lymph node involved site: Inguinal.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; Surgery, NOS, for progressive disease.

Follow-up (3 entries)
- Days to follow up: 163 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Vertebral column; Days to progression: 163 days.
- Days to follow up: 268 days; Disease response: With Tumor.
- Follow-up contact recording only the day: day 0.

Molecular and laboratory tests
- BCL2 (IHC): Positive.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MYC translocation (FISH): Positive.
- Lactate Dehydrogenase 1764 [Blood test normal range upper: 300].

Other clinical attributes
- Day 0: Weight: 38.5 kg; Height: 147 cm; BMI: 17.8.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample BLGSP-71-19-00108-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Spleen; Preservation method: Frozen; Days to sample procurement: 259 days; Method of sample procurement: Excisional Biopsy; Tissue collection type: Retrospective.
  Slide BLGSP-71-19-00108-01A-01-S1-HE: Section location: Top; Percent tumor cells: 5; Percent tumor nuclei: 30; Percent normal cells: 0; Percent necrosis: 90; Percent stromal cells: 5; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 5; Percent neutrophil infiltration: 0.
  Slide BLGSP-71-19-00108-01A-01-S2-HE: Section location: Bottom; Percent tumor cells: 5; Percent tumor nuclei: 10; Percent normal cells: 0; Percent necrosis: 90; Percent stromal cells: 5; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 5; Percent neutrophil infiltration: 0.
- Sample BLGSP-71-19-00108-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample BLGSP-71-19-00108-16A: Sample type: Mononuclear Cells from Bone Marrow Normal; Tissue type: Normal; Specimen type: Mononuclear Cells from Bone Marrow; Preservation method: Frozen; Days to sample procurement: 8 days; Method of sample procurement: Bone Marrow Aspirate; Tissue collection type: Retrospective.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Lost to follow-up: No; New tumor event diagnosis indicator: Yes.
- Primary pathology: Histologic diagnosis: diffuse small non-cleaved cell per medical record; Extranodal site involvement: 5; Extranodal involvment other: chest wall; Lymph nodes examined: Yes.
- Primary pathology, Pos lymph node locations: Pos lymph node location: Other Location, specify.
- Stage record, Ann arbor: B symptoms present indicator: No.
- Tests performed: LDH level: 1764.
- New tumor event: New tumor event type: Distant Metastasis; New tumor event site other: CSF and cervical spine C4-C6; New tumor event diagnosis evidence: Biopsy with Histologic Confirmation; New tumor event diagnosis evidence: Convincing Imaging; New tumor event surgery: No; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes.
